Somatic mutation profile of tumor specimen TARGET-10-PAPBZW-09A (aliquot TARGET-10-PAPBZW-09A-01D) from TARGET case TARGET-10-PAPBZW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,137 days).
Specimen TARGET-10-PAPBZW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96c7c3a6-ef86-4758-aaf4-d48e9ec76f9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPBZW-10A (Blood Derived Normal), aliquot TARGET-10-PAPBZW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e23c5fdb-0e38-4f69-a72d-1dc47b312992

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CES1 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as rs752078237; called by muse, mutect2
- HAPLN3 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.892); catalogued as rs549076731; called by muse, mutect2, varscan2
- PAX5 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63905553; called by muse, mutect2, varscan2
- MRPS25 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- SLC52A1 | c.461G>A p.S154N | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ZBTB9 | c.517T>A p.S173T | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZEB2 | c.3215A>G p.Q1072R | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- PCDHA4 | c.1353C>T p.N451= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs782636671, COSV63539191; called by muse, mutect2, varscan2
- SEC62 | c.550-140G>A | Intron (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
- SH3TC1 | c.172+301T>G | Intron (SNP) | VAF 49/127 reads (39%) | called by muse, mutect2, varscan2
